Somatic mutation profile of tumor specimen TCGA-FD-A5BY-01A (aliquot TCGA-FD-A5BY-01A-31D-A289-08) from TCGA case TCGA-FD-A5BY, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 63.2 years (23,080 days).
Specimen TCGA-FD-A5BY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac948807-9598-47ff-99f4-1de99ea67526.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A5BY-10A (Blood Derived Normal), aliquot TCGA-FD-A5BY-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f55b7f87-ef29-4bfc-b48d-1e67fa17d8bc

The open-access MAF lists 48 somatic variants for this specimen: 39 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 8, Nonsense Mutation 3, Splice Site 2, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS19 | c.3451G>A p.E1151K | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV50759011; called by muse, mutect2, varscan2
- ALG2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as COSV53060134; called by muse, mutect2
- ANKRD27 | c.389C>G p.S130* | Nonsense Mutation (SNP) | VAF 191/734 reads (26%) | catalogued as rs1295584941, COSV100043106; called by muse, mutect2, varscan2
- ANKRD30A | c.1774G>C p.D592H (on ENST00000611781; = p.D536H on NM_052997.2) | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV100654034, COSV64613505; called by muse, mutect2, varscan2
- ANKRD30A | c.2488G>C p.D830H (on ENST00000611781; = p.D774H on NM_052997.2) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as COSV100654037; called by mutect2, varscan2
- CCNI | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1456465577, COSV52959741; called by muse, mutect2, varscan2
- CDRT1 | c.968G>A p.G323D | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.038); catalogued as COSV99887852; called by muse, varscan2
- CEACAM7 | c.607C>A p.L203I | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.514); catalogued as COSV50073367; called by muse, mutect2
- DMD | c.7891C>T p.R2631C | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as rs769601403, COSV58922091; called by muse, mutect2, varscan2
- EPB41L3 | c.1684G>C p.G562R | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV59443950, COSV59450869; called by muse, mutect2, varscan2
- ETV1 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV54144890; called by muse, mutect2, varscan2
- F5 | c.3331G>A p.A1111T | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1487591680, COSV63125381; called by muse, mutect2, varscan2
- FAM83C | c.1924G>A p.G642S | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs761122449, COSV65583499; called by muse, mutect2, varscan2
- FLG | c.11953G>A p.D3985N | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV64241805, COSV64245865; called by muse, mutect2, varscan2
- IL11RA | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as rs1368332337, COSV58840822, COSV58840886; called by muse, mutect2, varscan2
- IQSEC2 | c.2008A>G p.T670A (on ENST00000642864 / NM_001111125.3; = p.T465A on NM_015075.2) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV64726421; called by muse, mutect2, varscan2
- LANCL2 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 40/101 reads (40%) | catalogued as COSV99635103; called by muse, mutect2, varscan2
- LRRTM4 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV101297713; called by muse, mutect2, varscan2
- LYG1 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs1277660668, COSV57915197; called by muse, mutect2, varscan2
- MAOB | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV65205852; called by muse, mutect2, varscan2
- MFSD5 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1203536490, COSV61565734; called by muse, mutect2, varscan2
- MYBL2 | c.2057G>A p.G686D | Missense Mutation (SNP) | VAF 141/419 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.36); catalogued as COSV53831144; called by muse, mutect2, varscan2
- POU3F4 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64539770; called by muse, mutect2, varscan2
- PPARA | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53079574; called by muse, mutect2, varscan2
- RAB37 | c.205-1G>T p.X69_splice (on ENST00000392613 / NM_001006638.3; = p.X62_splice on NM_175738.5) | Splice Site (SNP) | VAF 15/48 reads (31%) | catalogued as COSV61195513; called by muse, mutect2, varscan2
- RHOXF2B | c.180A>T p.L60F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.095); catalogued as COSV101003975; called by mutect2, varscan2
- RNF135 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs1567751133, COSV60433852; called by muse, mutect2, varscan2
- SEC24D | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54881158; called by muse, mutect2, varscan2
- SLC6A12 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs151111165; called by muse, mutect2, varscan2
- SLC6A3 | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.269); catalogued as rs553219765, COSV54365656; called by muse, mutect2, varscan2
- SPOCK1 | c.1045C>A p.H349N | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV56453616; called by muse, mutect2, varscan2
- STX18 | c.456G>C p.Q152H | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV60373891; called by muse, mutect2, varscan2
- SYNJ2 | c.1308C>A p.H436Q | Missense Mutation (SNP) | VAF 117/212 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV62898343; called by muse, mutect2, varscan2
- TAF2 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 30/63 reads (48%) | catalogued as COSV100558404; called by muse, mutect2, varscan2
- TLR3 | c.2164C>G p.L722V | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.529); catalogued as rs1028373125, COSV57169180; called by muse, mutect2, varscan2
- TRPM6 | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs535775554, COSV62514529; called by muse, mutect2, varscan2
- TSPAN9 | c.610G>C p.V204L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV50724849; called by muse, mutect2, varscan2
- GALNT16 | c.136_141del p.R46_S47del | In Frame Del (DEL) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- PIK3R1 | c.1740_1745+3del p.X580_splice (on ENST00000521381 / NM_181523.3; = p.X310_splice on NM_181504.4) | Splice Site (DEL) | VAF 29/54 reads (54%) | called by mutect2, pindel, varscan2
- KCNC4 | c.1698G>A p.P566= | Silent (SNP) | VAF 45/129 reads (35%) | catalogued as rs371724703; called by muse, mutect2, varscan2
- OR4K13 | c.546C>T p.P182= | Silent (SNP) | VAF 45/132 reads (34%) | catalogued as rs915292468, COSV59859621; called by muse, mutect2, varscan2
- RAB42 | c.153C>T p.C51= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs370993430, COSV65753124; called by muse, mutect2, varscan2
- RNF135 | c.816G>A p.L272= | Silent (SNP) | VAF 62/180 reads (34%) | catalogued as rs756758868, COSV60433848; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC38A2 | c.1455G>T p.V485= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV56744558, COSV56745457; called by muse, mutect2, varscan2
- TACC2 | c.801G>A p.E267= | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as rs768595912, COSV57760264; called by muse, mutect2, varscan2
- TLN2 | c.2817G>A p.Q939= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV100169887; called by muse, mutect2, varscan2
- ZNF608 | c.960C>T p.L320= | Silent (SNP) | VAF 47/83 reads (57%) | catalogued as rs1436252513, COSV60437055; called by muse, mutect2, varscan2
- RUSC1 | c.-121A>G | 5'UTR (SNP) | VAF 19/59 reads (32%) | catalogued as COSV99430219; called by muse, mutect2, varscan2
